Gene-level copy-number profile of tumor specimen TCGA-DX-A1KU-01A from TCGA case TCGA-DX-A1KU, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 82.3 years (30,054 days).
Specimen TCGA-DX-A1KU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.48b516b7-49be-422c-952d-078a99276d70.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DX-A1KU-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/78470328-d3e8-427a-8ee5-b12c7eff07b7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 15; copy number 2: 12,351; copy number 3: 17,777; copy number 4: 23,252; copy number 5: 2,607; copy number 6: 1,921; copy number 7: 567; copy number 8: 154; copy number 9: 313; copy number 10: 107; copy number 11: 71; copy number 12: 20; copy number 13: 62; copy number 14: 107; copy number 15: 101; copy number 16: 52; copy number 17: 77; copy number 20: 84; copy number 21: 13; copy number 22: 2; copy number 23: 7; copy number 25: 16; copy number 26: 7; copy number 29: 9; copy number 30: 15; copy number 32: 18; copy number 34: 13; copy number 36: 50; copy number 50: 25.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DX-A1KU-01A-32D-A24M-01): tumor purity 0.45, ploidy 3.24, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,169 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,288,596–148,288,951, 61 genes, copy number 17 (broad region; genes not listed).
- chr1:148,295,180–148,358,686, 7 genes, copy number 17: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6.
- chr1:151,747,597–152,445,456, 36 genes, copy number 9 (within-gene range 3–9): RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28, S100A10, AL450992.1, NBPF18P, S100A11, SPTLC1P4, AL591893.1, TCHHL1, TCHH, AL589986.1, PUDPP2, RPTN, FLG-AS1, AL589986.2, HRNR, FLG.
- chr1:156,815,640–164,357,364, 257 genes, copy number 9–16 (within-gene range 3–16) (broad region; genes not listed).
- chr1:165,201,867–165,356,715, 3 genes, copy number 10: LMX1A, LMX1A-AS2, LMX1A-AS1.
- chr1:165,476,838–166,682,196, 33 genes, copy number 15: LRRC52-AS1, PRELID1P7, LRRC52, AL356441.2, AL356441.1, MGST3, ALDH9A1, Y_RNA, AL451074.3, AL451074.2, AL451074.1, AL451074.5, TMCO1, TMCO1-AS1, AL451074.4, UCK2, AL358115.1, MIR3658, AL606495.1, RPS3AP10, RNA5SP64, FAM78B, FAM78B-AS1, AL596087.3, MIR921, AL596087.2, AL596087.1, AL583804.1, FMO7P, LINC01675, FMO8P, FMO9P, FMO10P.
- chr1:166,839,447–169,132,722, 60 genes, copy number 10–21 (within-gene range 2–21): POGK, TADA1, DUTP6, ILDR2, MAEL, RNA5SP65, AL158837.1, GPA33, STYXL2, AL451050.1, LINC01363, AL451050.2, POU2F1, AL136984.1, CD247, AL359962.3, AL359962.1, AL359962.2, AKR1D1P1, CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P, TBX19, AL022100.1, MIR557, AL023755.1, AL022100.2, QRSL1P1, XCL2, AL031736.1, XCL1, AL031736.2, DPT, AL135926.1, AL031275.1, LINC00626, SUMO1P2, AL135926.2, LINC00970, RPL29P7, AL031726.2, RNA5SP66, AL031726.1, ATP1B1.
- chr1:169,310,665–169,460,669, 3 genes, copy number 15 (within-gene range 6–15): Z99758.1, BLZF1, CCDC181.
- chr1:169,588,849–169,854,080, 3 genes, copy number 17–20 (within-gene range 4–20): SELP, C1orf112, SELL.
- chr1:169,762,929–174,160,165, 101 genes, copy number 9–26 (within-gene range 3–26) (broad region; genes not listed).
- chr1:176,463,171–176,845,601, 3 genes, copy number 11 (within-gene range 6–11): PAPPA2, PTP4A1P7, AL031290.1.
- chr1:177,170,958–178,484,147, 10 genes, copy number 14 (within-gene range 5–23): BRINP2, LINC01645, AL136114.1, LINC01741, SEC16B, CRYZL2P-SEC16B, CRYZL2P, AL359075.1, RASAL2-AS1, RASAL2.
- chr1:178,411,616–178,561,029, 7 genes, copy number 23: AL365357.1, CLEC20A, Metazoa_SRP, AL513013.1, TEX35, C1orf220, RNA5SP69.
- chr1:179,025,804–179,554,735, 16 genes, copy number 16 (within-gene range 3–16): FAM20B, AL139132.1, TOR3A, ABL2, AL512326.5, SETP10, AL512326.2, AL512326.1, EIF4A1P11, AL512326.3, COX5BP8, AL512326.4, SOAT1, AXDND1, MEF2AP1, HNRNPA1P54.
- chr1:180,632,022–181,061,938, 10 genes, copy number 11 (within-gene range 3–11): XPR1, U6, LINC02816, KIAA1614, AL162431.1, KIAA1614-AS1, AL162431.2, AL162431.3, STX6, MR1.
- chr1:185,630,428–186,190,949, 4 genes, copy number 10 (within-gene range 4–10): Y_RNA, Y_RNA, AL133383.1, HMCN1.
- chr1:193,012,250–193,365,953, 9 genes, copy number 14 (within-gene range 4–14): UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031.
- chr1:197,038,741–197,478,455, 8 genes, copy number 13 (within-gene range 4–13): F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1.
- chr1:199,752,491–200,014,795, 6 genes, copy number 12: AL596266.1, AL445687.1, RNU6-778P, AL445687.2, RNU6-716P, RNU6-609P.
- chr1:229,570,532–229,892,046, 6 genes, copy number 9 (within-gene range 3–9): HMGN2P19, TAF5L, URB2, AL354983.1, HMGB1P26, LINC01682.
- chr2:125,665,331–126,343,992, 7 genes, copy number 15: AC097499.2, LINC01889, AC097499.1, LINC01941, AC142116.2, AC023347.1, SLC6A14P3.
- chr11:10,302,657–10,611,689, 9 genes, copy number 11: AC080023.1, ADM, AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141, IRAG1-AS1, LYVE1.
- chr11:10,751,246–11,243,715, 12 genes, copy number 10 (within-gene range 7–10): CTR9, EIF4G2, SNORD97, AC116535.1, ZBED5, ZBED5-AS1, AC069360.1, LINC02752, AC111188.1, AC111188.2, MTND5P21, KC877392.1.
- chr11:11,841,423–12,944,737, 18 genes, copy number 10: USP47, H3P33, DKK3, LINC02547, AC124276.1, AC124276.2, MICAL2, MIR6124, AC079329.1, AC025300.1, PARVA, AC009806.1, AC107881.1, TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1.
- chr11:13,001,090–16,758,340, 53 genes, copy number 9 (within-gene range 2–9): RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.3, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2, PSMA1, PDE3B, MORF4L1P3, CYP2R1, CALCB, CALCP, CALCA, OR7E41P, INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, AC009869.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58.
- chr11:18,322,295–19,308,358, 40 genes, copy number 11: GTF2H1, MIR3159, LDHA, AC084117.1, LDHC, AC027544.3, LDHAL6A, TSG101, YWHABP2, AC027544.2, AC027544.1, UEVLD, Metazoa_SRP, SPTY2D1OS, AC112694.1, AC112694.2, SPTY2D1, SRSF3P1, TMEM86A, IGSF22, AC103974.1, PTPN5, AC103974.2, MRGPRX8P, MRGPRX7P, AC023078.2, MRGPRX6P, MRGPRX5P, MRGPRX1, AC023078.1, MRGPRX11P, MRGPRX10P, MRGPRX9P, MRGPRX2, ZDHHC13, CSRP3, CSRP3-AS1, E2F8, PCNAP4, AC009652.1.
- chr11:20,043,846–21,575,686, 16 genes, copy number 10: NAV2-AS2, NAV2-AS1, AC068860.1, DBX1, HTATIP2, PRMT3, HMGB1P40, AC090707.2, SLC6A5, NELL1, AC090707.1, RNA5SP336, AC090857.1, AC090857.2, AC099730.1, RNA5SP337.
- chr11:22,622,533–22,945,393, 6 genes, copy number 12: FANCF, GAS2, RNA5SP338, SVIP, AC006299.1, CCDC179.
- chr11:23,370,116–23,521,202, 6 genes, copy number 12: AC100767.2, WIZP1, MIR8054, AC100767.1, THAP12P4, AC068472.1.
- chr12:46,239,106–48,146,404, 58 genes, copy number 15 (within-gene range 3–15): AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2, PCED1B, IFITM3P6, MIR4698, PCED1B-AS1, AC008083.2, AC008083.3, AC008083.4, PPIAP45, AC008083.1, LINC02416, MIR4494, LINC02156, ADI1P3, AC003686.1, AC004486.1, RPAP3, AC004241.3, AC004241.1, ENDOU, AC004241.5, AC004241.2, RAPGEF3, SLC48A1, AC004241.4, HDAC7, AC004466.1, AC004466.3, AC004466.2, LINC02354, VDR, AC121338.1, AC121338.2, AC004801.7, TMEM106C, COL2A1, AC004801.5, AC004801.4, AC004801.3, AC004801.6, SENP1, AC004801.2, RNU6-1203P, AC004801.1, PFKM, MIR6505.
- chr12:56,162,359–57,984,761, 115 genes, copy number 14–36 (within-gene range 3–36) (broad region; genes not listed).
- chr12:58,872,149–59,789,855, 13 genes, copy number 34 (within-gene range 5–34): LRIG3, AC068305.2, RPS6P22, AC068305.1, AC046129.1, AC108721.2, AC108721.1, RNU6-279P, RNU6-871P, LINC02448, RNU4-20P, SLC16A7, AC079905.2.
- chr12:62,021,570–62,417,431, 7 genes, copy number 16: RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP.
- chr12:65,466,820–65,966,291, 9 genes, copy number 29 (within-gene range 3–29): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1.
- chr12:66,023,620–66,343,643, 15 genes, copy number 30: MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7, RN7SKP166, HELB.
- chr12:67,443,105–69,699,476, 59 genes, copy number 25–50 (within-gene range 4–50): LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70, AC007458.1, IFNG, IL26, IL22, MDM1, LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3.
- chr12:70,906,917–71,800,286, 17 genes, copy number 14: Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1.
- chr12:71,938,845–74,664,141, 25 genes, copy number 9–22: TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1.
- chr12:75,333,798–75,984,015, 14 genes, copy number 10–13 (within-gene range 3–13): AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1, AC078923.1, AC022507.1, AC078820.2, RPL10P13, SNORA70, AC078820.1, AC011611.6, RN7SL734P.
- chr16:17,192,863–17,446,380, 5 genes, copy number 9: AC099494.1, AC099494.2, AC099494.3, AC009152.6, AC009152.1.

Autosomal genes at a single copy (total copy number 1): 15. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
